Somatic mutation profile of tumor specimen TCGA-43-3920-01A (aliquot TCGA-43-3920-01A-01D-0983-08) from TCGA case TCGA-43-3920, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 71.3 years (26,059 days).
Specimen TCGA-43-3920-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1465f830-49bc-4906-8168-6fb67316f40f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-43-3920-10A (Blood Derived Normal), aliquot TCGA-43-3920-10A-01D-0983-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff6520ef-56ca-41a1-96f3-3b8369386eea

The open-access MAF lists 294 somatic variants for this specimen: 221 protein-altering or splice-affecting, 67 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 195, Silent 67, Nonsense Mutation 13, Splice Region 5, Frame Shift Del 4, Intron 2, Splice Site 2, RNA 2, Frame Shift Ins 2, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP2C1 | c.2213A>G p.N738S | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs963144528, COSV60759411; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- OTOF | c.3178del p.A1060Qfs*86 (on ENST00000272371 / NM_194248.3; = p.A313Qfs*86 on NM_004802.4) | Frame Shift Del (DEL) | VAF 20/35 reads (57%) | catalogued as rs727504639; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 32/60 reads (53%) | catalogued as rs786202918, CM981673, COSV100910801, COSV64288504; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.578A>T p.H193L | Missense Mutation (SNP) | VAF 20/37 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AAR2 | c.528G>C p.Q176H | Missense Mutation (SNP) | VAF 67/133 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.099); catalogued as rs781069168, COSV57924459; called by muse, mutect2, varscan2
- ABCA1 | c.1003G>T p.G335* | Nonsense Mutation (SNP) | VAF 19/35 reads (54%) | catalogued as COSV66068466; called by muse, mutect2, varscan2
- ABCA6 | c.1305G>C p.L435F | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs1228085547, COSV52641649; called by muse, mutect2, varscan2
- ABCB5 | c.2596G>A p.D866N (on ENST00000404938 / NM_001163941.2; = p.D421N on NM_178559.6) | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.309); catalogued as COSV51715070; called by muse, varscan2
- ADAMTS18 | c.854C>G p.S285* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as COSV51417659, COSV51419530; called by muse, mutect2, varscan2
- ADCY3 | c.1258G>A p.V420M | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1004579539, COSV53170059; called by muse, mutect2, varscan2
- AFTPH | c.1759G>C p.A587P | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV53220042; called by muse, mutect2, varscan2
- AGO3 | c.2218G>T p.D740Y | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV55795197; called by muse, varscan2
- AGO3 | c.2242G>A p.D748N | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs1258851550, COSV55795208; called by muse, varscan2
- AHNAK2 | c.16090A>T p.M5364L | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV60922325; called by muse, mutect2, varscan2
- ANO4 | c.561A>T p.R187S (on ENST00000392977 / NM_001286615.2; = p.R152S on NM_178826.4) | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.116); catalogued as COSV54604811; called by muse, mutect2, varscan2
- AP3B2 | c.174G>A p.M58I | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV55611878; called by muse, varscan2
- AP3D1 | c.720G>C p.K240N | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61430847; called by muse, mutect2, varscan2
- APOB | c.6910A>G p.T2304A | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as COSV51944155; called by muse, mutect2, varscan2
- APOBEC4 | c.431C>T p.T144M | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as rs779521158, COSV58016901; called by mutect2, varscan2
- ARHGEF26 | c.1711A>G p.M571V | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62849064; called by muse, mutect2, varscan2
- ARID1B | c.4208G>T p.R1403L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs144424476, COSV51671392; called by muse, mutect2, varscan2
- ASTN1 | c.2002A>T p.M668L | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56076990; called by mutect2, varscan2
- ASTN1 | c.1553G>T p.G518V | Missense Mutation (SNP) | VAF 71/137 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV56064283; called by muse, mutect2, varscan2
- ATP8B4 | c.3116T>G p.M1039R | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.421); catalogued as COSV52719777; called by muse, mutect2, varscan2
- AVPR1B | c.959T>A p.F320Y | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.723); catalogued as COSV100899331, COSV65638372; called by muse, mutect2, varscan2
- BAZ1A | c.3295C>G p.P1099A | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62411262; called by muse, mutect2, varscan2
- BCAS1 | c.224C>A p.A75D | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65087963; called by muse, mutect2, varscan2
- C12orf50 | c.131G>C p.S44T | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.359); catalogued as COSV53897160; called by muse, mutect2, varscan2
- C1orf127 | c.925A>G p.K309E | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV65438039; called by muse, mutect2, varscan2
- C2CD5 | c.1687G>T p.G563* | Nonsense Mutation (SNP) | VAF 48/100 reads (48%) | catalogued as COSV61726062; called by muse, mutect2, varscan2
- C3orf22 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs372125033; called by mutect2, varscan2
- C9orf64 | c.497C>G p.S166C | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59032864; called by muse, mutect2, varscan2
- CACNG3 | c.709T>C p.S237P | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); catalogued as COSV50075554; called by muse, mutect2, varscan2
- CALCOCO1 | c.1048G>C p.E350Q | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.721); catalogued as COSV50417198; called by muse, mutect2, varscan2
- CAPN2 | c.1623G>C p.L541F | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); catalogued as COSV54337766; called by muse, mutect2, varscan2
- CAPN5 | c.1513G>T p.E505* (on ENST00000456580; = p.E465* on NM_004055.5) | Nonsense Mutation (SNP) | VAF 8/80 reads (10%) | catalogued as COSV53686106, COSV53689778; called by muse, mutect2, varscan2
- CCDC170 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53339395, COSV53343411; called by muse, mutect2, varscan2
- CCDC186 | c.1835A>G p.Q612R | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.439); catalogued as COSV65161746; called by muse, mutect2, varscan2
- CCP110 | c.1062C>G p.I354M | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as COSV101195287, COSV66817439; called by muse, mutect2, varscan2
- CD244 | c.1062C>G p.N354K (on ENST00000368033 / NM_001166663.2; = p.N349K on NM_016382.4) | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as rs930887807, COSV54435847; called by muse, mutect2, varscan2
- CDC42BPB | c.1456G>C p.E486Q | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV63476015; called by muse, mutect2, varscan2
- CDCA8 | c.602G>A p.G201D | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59239840; called by muse, mutect2, varscan2
- CDH20 | c.448G>C p.E150Q | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.738); catalogued as COSV53013839; called by muse, mutect2, varscan2
- CECR2 | c.448G>T p.D150Y | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99377675; called by mutect2, varscan2
- CELA2A | c.535C>G p.L179V | Missense Mutation (SNP) | VAF 126/210 reads (60%) | SIFT tolerated (0.32); PolyPhen benign (0.382); catalogued as COSV62747823; called by muse, mutect2, varscan2
- CELA3A | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51585326; called by muse, mutect2, varscan2
- CEP128 | c.947T>G p.L316R | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV53676660; called by muse, mutect2, varscan2
- CEP162 | c.2863G>T p.D955Y | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57621982; called by muse, mutect2, varscan2
- CFLAR | c.1249C>A p.H417N | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV58579324, COSV58581257; called by muse, varscan2
- CLVS2 | c.77C>A p.T26K | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.92); PolyPhen possibly damaging (0.726); catalogued as COSV51561523, COSV51566135; called by muse, mutect2, varscan2
- COL4A1 | c.3085G>T p.G1029C | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65428675; called by muse, mutect2, varscan2
- COP1 | c.461G>A p.S154N | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); catalogued as COSV58171581; called by muse, mutect2
- CREB5 | c.1130G>A p.R377K (on ENST00000357727 / NM_182898.4; = p.R370K on NM_004904.3) | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.982); catalogued as COSV63225240; called by muse, mutect2, varscan2
- CSMD3 | c.11081T>C p.V3694A (on ENST00000297405 / NM_001363185.1; = p.V3525A on NM_052900.3) | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.978); catalogued as COSV52090381, COSV52178179; called by muse, mutect2, varscan2
- CSMD3 | c.5788G>T p.D1930Y (on ENST00000297405 / NM_001363185.1; = p.D1826Y on NM_052900.3) | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.79); catalogued as COSV52184002, COSV52248180; called by muse, mutect2, varscan2
- CUEDC1 | c.787C>A p.R263= | Splice Region (SNP) | VAF 10/52 reads (19%) | catalogued as COSV64226802, COSV64226836; called by muse, mutect2
- CWF19L2 | c.1146G>T p.K382N | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as COSV56516341; called by muse, mutect2, varscan2
- CYP4F11 | c.1220T>A p.V407E | Missense Mutation (SNP) | VAF 50/68 reads (74%) | SIFT tolerated (0.49); PolyPhen benign (0.213); catalogued as COSV56128357; called by muse, varscan2
- DEF6 | c.671G>T p.W224L | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.145); catalogued as COSV57354710; called by muse, mutect2, varscan2
- DENND2C | c.2403C>G p.I801M (on ENST00000393274 / NM_001256404.2; = p.I744M on NM_198459.4) | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as COSV67920479, COSV67922866; called by muse, mutect2, varscan2
- DIP2A | c.4327G>A p.D1443N | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.809); catalogued as COSV59482408; called by muse, mutect2, varscan2
- DNAH11 | c.5807T>A p.V1936E | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV60967055; called by muse, mutect2, varscan2
- DSC3 | c.1705G>T p.D569Y | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV64574074; called by muse, mutect2, varscan2
- DSG1 | c.2255G>T p.G752V | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57137524; called by muse, mutect2, varscan2
- DUSP10 | c.874G>C p.E292Q | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV60458857; called by muse, mutect2, varscan2
- DUSP5 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.265); catalogued as COSV63646670; called by muse, mutect2, varscan2
- DZIP3 | c.1388A>T p.K463I | Missense Mutation (SNP) | VAF 78/159 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); catalogued as COSV64312879; called by muse, mutect2, varscan2
- EPHA3 | c.2847-2A>T p.X949_splice | Splice Site (SNP) | VAF 16/28 reads (57%) | catalogued as COSV60716010; called by muse, mutect2, varscan2
- ERICH3 | c.1668C>A p.D556E | Missense Mutation (SNP) | VAF 55/174 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as COSV58612617; called by muse, mutect2, varscan2
- ERMARD | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64648466; called by muse, mutect2, varscan2
- ESRRB | c.656C>A p.A219D | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV55064111; called by muse, mutect2, varscan2
- FAM135B | c.2520G>T p.Q840H | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV52739799; called by muse, mutect2, varscan2
- FAM234B | c.1039C>G p.Q347E | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as COSV52195989; called by muse, varscan2
- FBXO16 | c.599G>T p.R200L | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.097); catalogued as COSV60775821, COSV60777031; called by muse, mutect2, varscan2
- FGFBP2 | c.144C>G p.S48R | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV52588294; called by muse, mutect2, varscan2
- FMO1 | c.89G>A p.C30Y | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs777050491, COSV61446799; called by muse, mutect2, varscan2
- GALT | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.879); catalogued as rs758430398, CM012753, COSV66592761; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GBP4 | c.1696C>G p.H566D | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.944); catalogued as COSV63255223; called by muse, mutect2
- GDA | c.838G>A p.G280S | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.938); catalogued as rs551530651, COSV52991447; called by muse, mutect2, varscan2
- GNG4 | c.83G>T p.C28F | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV63999877; called by muse, mutect2, varscan2
- GPC5 | c.1145A>G p.N382S | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT tolerated (0.89); PolyPhen benign (0.01); catalogued as rs775793508, COSV65613153; called by muse, mutect2, varscan2
- GPR149 | c.1371C>A p.S457R | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.132); catalogued as COSV67668612; called by muse, mutect2
- GRIN3A | c.1106G>T p.G369V | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs780244243, COSV62456216; called by muse, mutect2, varscan2
- GSTA1 | c.578C>A p.T193K | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV58016167; called by muse, mutect2
- H2BC1 | c.10G>A p.V4M | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.015); catalogued as rs757799935, COSV51237786; called by muse, mutect2, varscan2
- HACE1 | c.430A>G p.T144A | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); catalogued as COSV53504826; called by muse, mutect2, varscan2
- HADHB | c.930C>G p.F310L | Missense Mutation (SNP) | VAF 64/104 reads (62%) | SIFT tolerated (0.13); PolyPhen benign (0.139); catalogued as COSV58547395; called by muse, varscan2
- HAO1 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757788996, COSV66492969; called by muse, mutect2, varscan2
- HAVCR1 | c.125T>C p.V42A | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV59401620; called by muse, mutect2, varscan2
- HEG1 | c.3227G>C p.R1076T | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV60760528, COSV60763904; called by muse, mutect2, varscan2
- HRC | c.2062C>G p.Q688E | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV53256838, COSV53257626; called by muse, mutect2, varscan2
- HSD17B12 | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as rs1280476644, COSV53501822; called by muse, mutect2, varscan2
- IL10 | c.188A>G p.N63S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs776711200, COSV65594766; called by muse, mutect2, varscan2
- IRF2BPL | c.1927G>A p.G643S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.05); catalogued as COSV53148071; called by muse, mutect2, varscan2
- ITGA11 | c.1688G>A p.G563E | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59880007; called by muse, mutect2, varscan2
- ITPRID1 | c.162G>T p.L54= | Splice Region (SNP) | VAF 9/26 reads (35%) | catalogued as COSV60078523; called by muse, mutect2, varscan2
- KIAA1549L | c.652G>T p.A218S (on ENST00000321505; = p.A515S on NM_012194.3) | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.081); catalogued as COSV55775532, COSV55777557; called by muse, mutect2, varscan2
- KPNA2 | c.49T>A p.F17I | Missense Mutation (SNP) | VAF 191/276 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57858325; called by muse, mutect2, varscan2
- KPRP | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV64221710, COSV64221721; called by muse, mutect2
- KREMEN1 | c.749C>T p.S250F (on ENST00000407188; = p.S252F on NM_032045.5) | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.857); catalogued as COSV59913798; called by muse, mutect2, varscan2
- KTN1 | c.865C>A p.L289M | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.184); catalogued as COSV68024567; called by muse, mutect2, varscan2
- LCT | c.4881G>T p.W1627C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV51553723; called by muse, mutect2, varscan2
- LCTL | c.763C>A p.L255M | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.085); catalogued as COSV58422594; called by muse, mutect2, varscan2
- LNX1 | c.2147T>C p.I716T (on ENST00000263925 / NM_001126328.3; = p.I620T on NM_032622.2) | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV55788875; called by muse, mutect2, varscan2
- LPA | c.4266G>C p.R1422S | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.467); catalogued as rs372776354, COSV60302556; called by muse, mutect2, varscan2
- LRP1 | c.13132G>T p.V4378F | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.73); PolyPhen benign (0.048); catalogued as COSV54518598; called by muse, mutect2, varscan2
- MAML2 | c.2483C>T p.S828F | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV73264178; called by muse, mutect2, varscan2
- MAN1A2 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62979721; called by muse, varscan2
- MAP4K4 | c.1430G>C p.R477P | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV56326751, COSV56336108; called by muse, mutect2, varscan2
- MARCHF10 | c.2295G>C p.M765I | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV60889194; called by muse, mutect2, varscan2
- MEGF8 | c.5258G>T p.R1753L (on ENST00000251268 / NM_001271938.2; = p.R1686L on NM_001410.3) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs201626121, COSV52073629, COSV52093392; called by muse, mutect2
- MFSD1 | c.1106T>C p.L369P | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1361586758, COSV51842139; called by muse, mutect2, varscan2
- MGAT5 | c.1832G>C p.G611A | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56098786; called by muse, mutect2, varscan2
- MICAL1 | c.1750C>A p.P584T | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57806297; called by muse, mutect2, varscan2
- MIEF1 | c.322+1G>A p.X108_splice | Splice Site (SNP) | VAF 10/58 reads (17%) | catalogued as COSV100307542, COSV57479198; called by muse, mutect2, varscan2
- MME | c.1000G>T p.V334L | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV64708979; called by muse, mutect2, varscan2
- MS4A14 | c.895G>T p.A299S | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV55734035; called by muse, mutect2, varscan2
- MS4A7 | c.347G>A p.S116N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as COSV55730904; called by muse, mutect2, varscan2
- MYH2 | c.4900C>A p.Q1634K | Missense Mutation (SNP) | VAF 43/63 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as COSV55443199; called by muse, mutect2, varscan2
- NCAM2 | c.2476G>T p.D826Y | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53089218; called by muse, mutect2, varscan2
- NCKAP5 | c.4814G>T p.R1605I | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.837); catalogued as COSV58460384; called by muse, mutect2, varscan2
- NDUFA10 | c.446A>C p.H149P | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53155557; called by muse, mutect2
- NUDT10 | c.*2G>T | Splice Region (SNP) | VAF 8/13 reads (62%) | catalogued as COSV100726812, COSV100726859; called by muse, mutect2, varscan2
- OPRD1 | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.577); catalogued as COSV52382856; called by muse, mutect2, varscan2
- OR10G8 | c.757C>A p.P253T | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70908955; called by mutect2, varscan2
- OR11L1 | c.816G>C p.K272N | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs932447104, COSV63315033; called by muse, mutect2, varscan2
- OR2T2 | c.412A>G p.N138D | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV100737659; called by muse, mutect2, varscan2
- OR2T3 | c.746A>T p.H249L | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62082927; called by muse, mutect2, varscan2
- OR2T4 | c.396G>T p.Q132H | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63544600; called by muse, mutect2, varscan2
- OR52E2 | c.106G>C p.V36L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV58613044; called by muse, mutect2, varscan2
- OR5AS1 | c.429C>A p.C143* | Nonsense Mutation (SNP) | VAF 28/70 reads (40%) | catalogued as COSV57982441, COSV57982495; called by muse, varscan2
- OR5I1 | c.127G>T p.G43W | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV56888149; called by muse, mutect2, varscan2
- OR8B4 | c.168C>A p.H56Q | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.607); catalogued as COSV62070177; called by muse, mutect2, varscan2
- PCDH11Y | c.553G>C p.A185P (on ENST00000400457 / NM_032973.2; = p.A174P on NM_032971.3) | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.995); catalogued as COSV53085734; called by muse, mutect2, varscan2
- PCDH19 | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM111236, COSV55267310; called by muse, mutect2, varscan2
- PCDHA2 | c.1534G>A p.A512T | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV100974185, COSV65369133; called by muse, mutect2, varscan2
- PDE8A | c.1688A>T p.D563V | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59638869; called by muse, mutect2, varscan2
- PGM1 | c.679G>T p.G227* | Nonsense Mutation (SNP) | VAF 45/161 reads (28%) | catalogued as COSV64301048; called by muse, mutect2, varscan2
- PI4KA | c.2646C>G p.I882M | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV55416812; called by muse, mutect2, varscan2
- PILRA | c.145G>T p.V49L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as COSV52201304; called by muse, varscan2
- PKHD1 | c.2824G>C p.G942R | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.124); catalogued as COSV61886778; called by muse, mutect2, varscan2
- PLEC | c.13541G>C p.G4514A (on ENST00000322810 / NM_201380.4; = p.G4404A on NM_000445.5) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59664018; called by muse, mutect2, varscan2
- PLEKHA5 | c.1781G>A p.R594K | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV54706581; called by muse, mutect2, varscan2
- PLXNA2 | c.1789G>T p.G597W | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV65442782; called by muse, mutect2, varscan2
- PPAT | c.1384G>A p.V462I | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as COSV51705543; called by muse, mutect2, varscan2
- PPP1R15A | c.1397C>G p.S466* | Nonsense Mutation (SNP) | VAF 10/81 reads (12%) | catalogued as COSV52339499, COSV52339692; called by muse, mutect2, varscan2
- PRDM9 | c.195T>C p.G65= | Splice Region (SNP) | VAF 29/77 reads (38%) | catalogued as COSV57010007; called by muse, mutect2, varscan2
- PRDM9 | c.1505A>T p.Q502L | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as COSV57010015; called by muse, mutect2, varscan2
- PROSER1 | c.1718T>A p.V573D | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.483); catalogued as COSV61488704; called by muse, mutect2, varscan2
- PTPRB | c.5888T>A p.V1963D | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54247310; called by muse, mutect2, varscan2
- RBM42 | c.202A>G p.T68A | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as rs1332838435, COSV52548898; called by muse, mutect2, varscan2
- RGS7 | c.901G>T p.D301Y | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV58533751, COSV58551113; called by muse, mutect2, varscan2
- RIMS1 | c.2791A>G p.R931G | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs1464512945, COSV53469301; called by muse, mutect2, varscan2
- RNF157 | c.1786G>A p.E596K | Missense Mutation (SNP) | VAF 215/284 reads (76%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.254); catalogued as COSV53941522; called by muse, mutect2, varscan2
- ROBO4 | c.1351A>C p.S451R | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV60626007; called by muse, mutect2, varscan2
- RUBCN | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.079); catalogued as rs533433095, COSV56370002; called by muse, mutect2, varscan2
- RYR2 | c.3475G>T p.G1159C | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63681003, COSV63699004; called by muse, mutect2, varscan2
- SCN10A | c.1253T>A p.F418Y | Missense Mutation (SNP) | VAF 52/94 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV71862236; called by muse, mutect2, varscan2
- SCN3A | c.4291G>C p.D1431H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as COSV51816928; called by muse, mutect2, varscan2
- SI | c.2663C>A p.T888K | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV52289862; called by muse, mutect2, varscan2
- SLC17A4 | c.340C>G p.L114V | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV64956714; called by muse, mutect2, varscan2
- SLC35G2 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.234); catalogued as COSV67588676; called by muse, mutect2, varscan2
- SLC38A6 | c.931G>C p.V311L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV50784080; called by muse, mutect2
- SLC6A12 | c.35C>A p.P12H | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.116); catalogued as COSV62885649; called by muse, mutect2, varscan2
- SLIT2 | c.1637C>T p.T546I | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV56583452; called by muse, mutect2, varscan2
- SMG1 | c.7910G>T p.C2637F | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV67173392; called by muse, mutect2, varscan2
- SPTA1 | c.4179G>T p.Q1393H | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV63756729; called by muse, mutect2, varscan2
- SRD5A2 | c.602G>A p.W201* | Nonsense Mutation (SNP) | VAF 53/87 reads (61%) | catalogued as COSV51872612; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.631C>A p.Q211K | Missense Mutation (SNP) | VAF 62/170 reads (36%) | PolyPhen benign (0.019); catalogued as rs745998079, COSV59564668; called by muse, varscan2
- STAB2 | c.616G>C p.E206Q | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.894); catalogued as COSV66342907; called by muse, mutect2, varscan2
- STAG1 | c.3176A>C p.D1059A | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV52616592; called by muse, mutect2, varscan2
- SYT2 | c.922C>G p.P308A | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66142532; called by muse, mutect2, varscan2
- SYT3 | c.1274G>A p.G425D | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV58897899; called by muse, mutect2, varscan2
- TAF1 | c.4930G>T p.V1644L (on ENST00000373790 / NM_138923.4; = p.V1665L on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/75 reads (68%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.006); catalogued as COSV52119553; called by muse, mutect2, varscan2
- TBCB | c.308G>C p.R103P | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs376064713; called by muse, mutect2, varscan2
- TDRD1 | c.818T>G p.F273C | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52593086; called by muse, mutect2, varscan2
- TENM3 | c.4115G>T p.R1372L | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.62); PolyPhen benign (0.026); catalogued as COSV69304543, COSV69313964; called by muse, mutect2, varscan2
- TFB2M | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV100830417, COSV63625045; called by muse, mutect2, varscan2
- THADA | c.4392C>G p.F1464L | Missense Mutation (SNP) | VAF 68/120 reads (57%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV57688457; called by muse, varscan2
- THEMIS | c.1516G>T p.V506L | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV64072662; called by muse, mutect2, varscan2
- THSD1 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.178); catalogued as rs763256441, COSV51628772, COSV99319032; called by muse, mutect2, varscan2
- THSD7B | c.211G>C p.V71L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV55712704; called by muse, mutect2, varscan2
- THSD7B | c.1175G>T p.G392V | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.571); catalogued as COSV55683904, COSV55712725; called by muse, mutect2, varscan2
- THSD7B | c.1378C>A p.P460T | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV55712744; called by muse, mutect2, varscan2
- TIGD7 | c.1405G>C p.E469Q | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.404); catalogued as COSV51915906; called by muse, mutect2, varscan2
- TLK1 | c.1058C>G p.T353R | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV62631506; called by muse, mutect2, varscan2
- TM9SF4 | c.1332G>A p.V444= | Splice Region (SNP) | VAF 58/124 reads (47%) | catalogued as rs544720237, COSV54109330; called by muse, varscan2
- TMC7 | c.324G>C p.E108D | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.067); catalogued as COSV58585557; called by muse, mutect2, varscan2
- TMCC1 | c.1110A>T p.R370S (on ENST00000393238 / NM_001349268.2; = p.R46S on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/82 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV61441808; called by muse, mutect2, varscan2
- TMEM117 | c.1319C>A p.S440* | Nonsense Mutation (SNP) | VAF 33/83 reads (40%) | catalogued as COSV56911535; called by muse, mutect2, varscan2
- TMEM160 | c.279C>A p.D93E | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.237); catalogued as COSV53409535; called by muse, mutect2, varscan2
- TMEM225 | c.280C>G p.Q94E | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV66693738; called by muse, mutect2, varscan2
- TNNI3K | c.2102G>A p.G701E | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV58560253; called by muse, mutect2, varscan2
- TNP2 | c.138C>G p.S46R | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.911); catalogued as COSV57129857; called by muse, mutect2, varscan2
- TRIM48 | c.274C>G p.L92V | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.098); catalogued as COSV70161232, COSV70162489; called by muse, mutect2, varscan2
- TRPM1 | c.4361A>G p.Q1454R | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV56638195; called by muse, mutect2, varscan2
- TRPM6 | c.2411G>C p.R804T | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV100666728, COSV62516823; called by muse, mutect2, varscan2
- TSC22D1 | c.1454G>T p.G485V | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1463523613, COSV71775939; called by muse, mutect2, varscan2
- TTN | c.69753T>A p.S23251R (on ENST00000591111; = p.S15827R on NM_003319.4) | Missense Mutation (SNP) | VAF 21/51 reads (41%) | PolyPhen possibly damaging (0.839); catalogued as COSV100592908, COSV60196350; called by muse, mutect2, varscan2
- TTN | c.15178G>T p.D5060Y (on ENST00000591111; = p.D4133Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/44 reads (48%) | PolyPhen probably damaging (0.961); catalogued as COSV60196394; called by muse, mutect2, varscan2
- TXNRD2 | c.1303G>T p.E435* | Nonsense Mutation (SNP) | VAF 22/200 reads (11%) | catalogued as COSV68692788; called by muse, mutect2, varscan2
- UBE4B | c.3238G>A p.E1080K (on ENST00000343090 / NM_001105562.3; = p.E951K on NM_006048.5) | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53536810; called by muse, varscan2
- UBN1 | c.1889G>A p.G630E | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.709); catalogued as COSV52170337; called by muse, mutect2, varscan2
- USP13 | c.2534C>G p.S845* | Nonsense Mutation (SNP) | VAF 64/267 reads (24%) | catalogued as COSV55868365; called by muse, mutect2, varscan2
- USP21 | c.841A>T p.T281S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV57090062; called by muse, mutect2, varscan2
- UXS1 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.267); catalogued as COSV51680217; called by muse, mutect2, varscan2
- VEZT | c.4A>G p.T2A | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54141940; called by muse, mutect2, varscan2
- WDR11 | c.3472G>A p.E1158K | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as rs141544883; called by muse, varscan2
- WDR11 | c.3499G>T p.E1167* | Nonsense Mutation (SNP) | VAF 24/80 reads (30%) | catalogued as COSV54790525; called by muse, varscan2
- WNK2 | c.991A>T p.I331F | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52950756; called by muse, mutect2, varscan2
- XCR1 | c.193C>T p.L65F | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs201298985, COSV58570096; called by muse, mutect2, varscan2
- ZAP70 | c.921del p.M308Cfs*25 | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | catalogued as COSV99385168; called by mutect2, pindel, varscan2
- ZDHHC17 | c.569G>C p.G190A | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV58352931; called by muse, mutect2
- ZFHX4 | c.2476G>T p.A826S | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); catalogued as COSV51473792; called by muse, mutect2, varscan2
- ZFHX4 | c.4544C>A p.S1515Y | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV51473804; called by muse, mutect2, varscan2
- ZNF254 | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 46/79 reads (58%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.613); catalogued as COSV61643750; called by muse, mutect2, varscan2
- ZPBP | c.733C>A p.P245T | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.022); catalogued as COSV50429092; called by muse, mutect2, varscan2
- FBLN5 | c.507dup p.D170* | Frame Shift Ins (INS) | VAF 8/49 reads (16%) | called by mutect2, pindel, varscan2
- KANSL2 | c.1323dup p.A442Cfs*2 | Frame Shift Ins (INS) | VAF 6/17 reads (35%) | called by mutect2, pindel, varscan2
- PCDHGA9 | c.770del p.P257Qfs*51 | Frame Shift Del (DEL) | VAF 22/54 reads (41%) | called by mutect2, pindel, varscan2
- SLC11A1 | c.596_597del p.F199Wfs*14 | Frame Shift Del (DEL) | VAF 41/263 reads (16%) | called by mutect2, pindel, varscan2
- AGK | c.456C>T p.I152= | Silent (SNP) | VAF 45/86 reads (52%) | catalogued as COSV62595260; called by muse, mutect2, varscan2
- ALPK3 | c.4557G>A p.L1519= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV51936384; called by muse, mutect2, varscan2
- ARHGEF16 | c.1086C>T p.I362= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV65682577; called by muse, mutect2, varscan2
- ARMC2 | c.96A>G p.E32= | Silent (SNP) | VAF 45/109 reads (41%) | catalogued as COSV52900970; called by muse, mutect2, varscan2
- CCDC185 | c.1614G>A p.L538= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as COSV64821361; called by muse, mutect2, varscan2
- CEP170B | c.315C>T p.V105= (on ENST00000453495; = p.V35= on NM_015005.3) | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as COSV69025573; called by muse, mutect2, varscan2
- CHPF | c.1833C>T p.F611= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as COSV60535909; called by muse, mutect2, varscan2
- COL28A1 | c.2982A>G p.S994= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as rs764013924, COSV68083428; called by muse, mutect2, varscan2
- CTNNA2 | c.90A>C p.P30= | Silent (SNP) | VAF 34/58 reads (59%) | catalogued as COSV63584816, COSV63601730; called by muse, mutect2, varscan2
- CYSLTR2 | c.360C>G p.V120= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV56166449; called by muse, mutect2, varscan2
- DCDC1 | c.2670G>A p.K890= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV100338092, COSV60309243; called by muse, mutect2
- DCST2 | c.127C>T p.L43= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV55053141; called by muse, mutect2, varscan2
- DENND5A | c.2925A>G p.P975= | Silent (SNP) | VAF 98/202 reads (49%) | catalogued as COSV60236035; called by muse, mutect2, varscan2
- DNAH5 | c.12765C>T p.V4255= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as rs561983296, COSV54239511; called by muse, mutect2, varscan2
- DNAH9 | c.4911C>G p.A1637= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV52362390; called by muse, mutect2, varscan2
- DPYD | c.526C>T p.L176= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as COSV64607008; called by muse, mutect2, varscan2
- ECE1 | c.1173C>T p.N391= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV51667389; called by mutect2, varscan2
- F7 | c.387C>T p.I129= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV60645606; called by muse, mutect2, varscan2
- FLG | c.8277T>C p.T2759= | Silent (SNP) | VAF 20/325 reads (6%) | catalogued as COSV64244914; called by muse, mutect2
- FOLH1 | c.756T>A p.G252= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV57052793; called by muse, mutect2, varscan2
- GLCCI1 | c.924G>A p.K308= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV56203526; called by muse, mutect2, varscan2
- HPGD | c.645A>G p.K215= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV56663580; called by muse, mutect2, varscan2
- IFNA5 | c.6C>A p.A2= | Silent (SNP) | VAF 22/34 reads (65%) | catalogued as COSV52387257; called by mutect2, varscan2
- INSM2 | c.858C>A p.I286= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs540516375, COSV51887687, COSV51889711; called by muse, mutect2, varscan2
- KALRN | c.8130G>T p.V2710= (on ENST00000360013 / NM_001024660.4; = p.V1013= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as COSV52260764; called by muse, mutect2, varscan2
- KY | c.528C>G p.L176= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs571652553, COSV71018077; called by muse, mutect2, varscan2
- MARF1 | c.5184C>G p.V1728= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as COSV60026223; called by muse, mutect2, varscan2
- MEI1 | c.282C>T p.F94= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs147144334; called by mutect2, varscan2
- MT1A | c.156G>C p.G52= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV51947729; called by muse, mutect2, varscan2
- MTMR11 | c.420G>T p.L140= (on ENST00000439741 / NM_001145862.2; = p.L68= on NM_181873.3) | Silent (SNP) | VAF 38/73 reads (52%) | catalogued as COSV63807440; called by muse, mutect2, varscan2
- MUC15 | c.774C>T p.Y258= | Silent (SNP) | VAF 49/108 reads (45%) | catalogued as COSV55555927; called by muse, mutect2, varscan2
- MYCBP2 | c.8223G>A p.L2741= (on ENST00000357337; = p.L2779= on NM_015057.5) | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as COSV62029510; called by muse, varscan2
- NEIL2 | c.525G>T p.L175= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as COSV52707354; called by muse, varscan2
- NOP9 | c.1335C>G p.L445= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV51866895; called by muse, mutect2, varscan2
- NOX4 | c.1566A>T p.G522= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as COSV54458962; called by muse, mutect2
- NRIP2 | c.255C>G p.L85= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as rs781203390, COSV61701812; called by muse, mutect2, varscan2
- OR11H4 | c.765G>A p.L255= | Silent (SNP) | VAF 47/106 reads (44%) | catalogued as COSV59560590; called by muse, mutect2, varscan2
- OR1D2 | c.699G>A p.K233= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as COSV58922001; called by muse, mutect2, varscan2
- OR5J2 | c.576C>T p.T192= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs1325286230, COSV56622333; called by muse, mutect2, varscan2
- OR5L1 | c.891G>T p.V297= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV61733049, COSV61734744; called by muse, mutect2, varscan2
- OR8H2 | c.592C>T p.L198= | Silent (SNP) | VAF 60/145 reads (41%) | catalogued as COSV57946402; called by muse, mutect2, varscan2
- PIK3R4 | c.1152C>G p.S384= | Silent (SNP) | VAF 39/198 reads (20%) | catalogued as COSV63242472; called by muse, mutect2, varscan2
- PIKFYVE | c.90T>C p.F30= | Silent (SNP) | VAF 48/130 reads (37%) | catalogued as rs1304945653, COSV52245325; called by muse, mutect2, varscan2
- PPP1R12C | c.2331C>T p.I777= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV99136112; called by muse, mutect2, varscan2
- PSD2 | c.522C>T p.V174= | Silent (SNP) | VAF 14/22 reads (64%) | catalogued as COSV51204522; called by muse, varscan2
- PTCHD3 | c.1458G>A p.A486= | Silent (SNP) | VAF 49/77 reads (64%) | catalogued as rs140478412; called by muse, mutect2, varscan2
- PTPRM | c.1965G>A p.L655= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as COSV59870700; called by muse, mutect2, varscan2
- R3HDM2 | c.1947G>A p.V649= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV61291935; called by muse, mutect2, varscan2
- RETREG1 | c.1065T>C p.N355= (on ENST00000306320 / NM_001034850.2; = p.N214= on NM_019000.4) | Silent (SNP) | VAF 44/92 reads (48%) | catalogued as COSV60450483; called by muse, mutect2, varscan2
- RGS7 | c.900T>C p.P300= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV58551128; called by muse, mutect2, varscan2
- RNF152 | c.399G>T p.V133= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV57186791; called by muse, mutect2, varscan2
- ROR1 | c.2490G>A p.A830= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs146764088; called by muse, mutect2, varscan2
- RPAP3 | c.432C>T p.F144= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV50042359; called by muse, mutect2, varscan2
- SDK1 | c.2628G>T p.V876= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV67379768; called by muse, mutect2, varscan2
- SEL1L3 | c.1401C>T p.H467= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as rs760964030, COSV53545548; called by muse, mutect2, varscan2
- SPDYE3 | c.1542C>T p.F514= | Silent (SNP) | VAF 96/145 reads (66%) | catalogued as rs1006184847, COSV60107563; called by muse, mutect2, varscan2
- SPRED3 | c.222G>A p.K74= | Silent (SNP) | VAF 17/122 reads (14%) | catalogued as rs767819506, COSV58313340; called by muse, mutect2, varscan2
- STT3A | c.240G>A p.L80= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV67065187; called by muse, mutect2
- SYNE1 | c.36G>T p.R12= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV55018816, COSV55038328; called by muse, mutect2, varscan2
- TEX101 | c.9G>A p.A3= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV53662480, COSV99494647; called by muse, mutect2, varscan2
- TOPBP1 | c.4305A>T p.T1435= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV53438974; called by muse, mutect2, varscan2
- TTN | c.34863C>A p.T11621= (on ENST00000591111; = p.T10694= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV60196380, COSV60413334; called by muse, mutect2, varscan2
- UNC5C | c.1065C>A p.L355= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as COSV71659473, COSV71661175; called by muse, mutect2, varscan2
- VN1R4 | c.270C>A p.G90= | Silent (SNP) | VAF 5/28 reads (18%) | called by mutect2, varscan2
- WWP2 | c.442C>T p.L148= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV63126209; called by muse, mutect2, varscan2
- XIAP | c.819G>A p.G273= | Silent (SNP) | VAF 32/46 reads (70%) | catalogued as COSV63023017; called by muse, mutect2, varscan2
- ZNF862 | c.870C>T p.I290= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV56224968; called by muse, mutect2, varscan2
- DDO | c.-24G>T | 5'UTR (SNP) | VAF 20/62 reads (32%) | catalogued as COSV64470310; called by muse, mutect2, varscan2
- FAM153CP | chr5:178055911 G>A | 3'Flank (SNP) | VAF 8/44 reads (18%) | catalogued as rs774739449; called by mutect2, varscan2
- PLB1 | c.2321+298G>A | Intron (SNP) | VAF 35/56 reads (63%) | catalogued as COSV100215071; called by muse, mutect2, varscan2
- RPL23AP82 | n.681A>G | RNA (SNP) | VAF 8/34 reads (24%) | catalogued as rs782687418; called by muse, mutect2, varscan2
- RPL26P30 | n.975_977del | RNA (DEL) | VAF 12/32 reads (38%) | catalogued as rs759849233; called by pindel, varscan2
- TTN | c.10360+1220C>A | Intron (SNP) | VAF 33/149 reads (22%) | catalogued as COSV60196404; called by muse, mutect2, varscan2
